Somatic mutation profile of tumor specimen TCGA-WK-A8XT-01A (aliquot TCGA-WK-A8XT-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 41.0 years (14,958 days).
Specimen TCGA-WK-A8XT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 967aebfb-d04b-4aa5-b661-a51426895218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XT-10A (Blood Derived Normal), aliquot TCGA-WK-A8XT-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/026b7e0b-961a-494c-852f-61b74dcc4c3c

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP6 | c.1201G>C p.A401P | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV100984224; called by muse, mutect2, varscan2
- ACSL4 | c.2010G>C p.K670N (on ENST00000340800 / NM_022977.2; = p.K629N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100538618, COSV61616252; called by muse, mutect2, varscan2
- ADCY2 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100602998; called by muse, mutect2, varscan2
- AHNAK2 | c.7109C>G p.P2370R | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV100317693; called by muse, mutect2, varscan2
- ALDH1L1 | c.454T>A p.C152S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV99856885; called by muse, mutect2, varscan2
- ANAPC2 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as rs775846010, COSV100119093; called by muse, mutect2, varscan2
- ARHGAP30 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100920283; called by muse, mutect2, varscan2
- BARD1 | c.1508A>C p.K503T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99638806; called by muse, mutect2, varscan2
- BAZ1B | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as COSV100289819; called by muse, mutect2, varscan2
- BEND3 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100944615; called by muse, mutect2, varscan2
- CLUH | c.2269G>C p.G757R (on ENST00000435359; = p.G796R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV101425756; called by muse, mutect2, varscan2
- COL12A1 | c.3695G>T p.G1232V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100485650; called by muse, mutect2, varscan2
- DNAH8 | c.8020A>G p.K2674E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as COSV100545629; called by muse, mutect2, varscan2
- DOK2 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs552782288, COSV99374755; called by muse, mutect2, varscan2
- EML2 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754269387, COSV55599733, COSV99840071; called by muse, mutect2, varscan2
- FGD6 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100676610; called by muse, mutect2, varscan2
- GLI3 | c.2369T>C p.F790S | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV101229897; called by muse, mutect2, varscan2
- HCFC1 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.766); catalogued as rs1418284758, COSV100129128; called by muse, mutect2, varscan2
- ITGB8 | c.775del p.A259Pfs*24 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV99751349; called by mutect2, pindel, varscan2
- JAG1 | c.2221A>C p.N741H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV99652965; called by muse, mutect2, varscan2
- KCNQ1 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99327133; called by muse, mutect2, varscan2
- LRRC34 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.548); catalogued as COSV100336324; called by muse, mutect2, varscan2
- MAGEA11 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.291); catalogued as rs782311651, COSV100290531; called by muse, mutect2, varscan2
- MTMR14 | c.821A>G p.Q274R | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99931323; called by muse, mutect2, varscan2
- MYH4 | c.2701G>C p.A901P | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99701388; called by muse, mutect2, varscan2
- NIBAN1 | c.1637A>G p.H546R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.439); catalogued as COSV100836407; called by muse, mutect2, varscan2
- PAN2 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99228303; called by muse, mutect2, varscan2
- PDE4A | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1286242826, COSV99534289; called by muse, mutect2, varscan2
- PDS5A | c.3167A>G p.N1056S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100337439; called by muse, mutect2, varscan2
- RGS12 | c.4005G>T p.E1335D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100122951; called by muse, mutect2, varscan2
- RNF165 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs754534844, COSV99491716; called by muse, mutect2, varscan2
- SIPA1L1 | c.4423C>G p.P1475A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.912); catalogued as COSV100665607; called by muse, mutect2, varscan2
- SLC43A2 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100024992; called by muse, mutect2, varscan2
- TNK1 | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100294858; called by muse, mutect2, varscan2
- TSKU | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs746280586, COSV100290102; called by muse, mutect2
- UBE2C | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99708627; called by muse, mutect2, varscan2
- ZFHX4 | c.1805G>C p.G602A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.846); catalogued as COSV99263300; called by muse, mutect2, varscan2
- ZFP57 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100971881; called by muse, mutect2, varscan2
- ABHD10 | c.866_876del p.L289Hfs*3 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- AOC3 | c.2226G>A p.L742= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100396074; called by muse, mutect2, varscan2
- CDH6 | c.2028C>G p.T676= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs757005899, COSV99419359; called by muse, mutect2, varscan2
- CX3CR1 | c.546C>G p.V182= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as COSV100843202; called by muse, mutect2, varscan2
- GDNF | c.114C>G p.L38= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1286995193, COSV100427465, COSV58481260; called by muse, mutect2, varscan2
- MCL1 | c.363G>T p.S121= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100329582; called by mutect2, varscan2
- NWD1 | c.616A>C p.R206= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100342739; called by muse, mutect2, varscan2
- PKHD1 | c.8133C>T p.V2711= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100580717; called by muse, mutect2, varscan2
- SERPINA4 | c.519C>T p.Y173= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs764068417, COSV54069007; called by muse, mutect2, varscan2
- SPATA6L | c.552C>T p.A184= (on ENST00000461761 / NM_001353484.2; = p.A126= on NM_001039395.4 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV99794962; called by muse, mutect2
- TRIB2 | c.144G>C p.P48= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV99331129; called by muse, mutect2, varscan2
- TRIM35 | c.129G>A p.G43= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- TTC3 | c.2751C>A p.A917= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV100695596; called by muse, mutect2, varscan2
- WDFY3 | c.498G>A p.V166= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV99883742; called by muse, mutect2, varscan2
- ZNF839 | c.1545G>T p.R515= (on ENST00000558850 / NM_001267827.1; = p.R631= on NM_018335.5) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99216267; called by muse, mutect2
- SLC41A3 | c.1366+66G>C | Intron (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100259638; called by muse, mutect2, varscan2
